Somatic mutation profile of tumor specimen BA2622D (aliquot aq-BA2622D) from BEATAML1.0 case 2453, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 76.4 years (27,908 days).
Specimen BA2622D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 922c6458-7aa5-4f96-8005-ab4757e68a99.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2205D (Solid Tissue Normal), aliquot aq-BA2205D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f40d9e45-723c-4770-9511-54a7c61dd144

The open-access MAF lists 12 somatic variants for this specimen: 12 protein-altering or splice-affecting.
By variant classification: Missense Mutation 11, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AS3MT | c.130C>T p.R44W | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.677); catalogued as rs1564789532, COSV54915979; called by muse, mutect2, varscan2
- GPR101 | c.946G>T p.G316C | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV53237686; called by muse, mutect2
- IKBKG | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as CD141303; called by muse, mutect2, varscan2
- SF3B1 | c.1986C>G p.H662Q | Missense Mutation (SNP) | VAF 78/292 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs778467242, COSV59205547, COSV59208501; called by muse, mutect2, varscan2
- SPTBN5 | c.1962G>C p.W654C | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.315); catalogued as COSV100311958; called by muse, mutect2, varscan2
- SUSD5 | c.1538C>T p.T513M | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.732); catalogued as rs372702857; called by muse, mutect2, varscan2
- CHADL | c.1624G>T p.G542W | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2
- GEMIN4 | c.195G>T p.W65C | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KRT38 | c.908G>T p.S303I | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- RIMBP3 | c.2615A>T p.D872V | Missense Mutation (SNP) | VAF 34/394 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- RUNX1 | c.931del p.A311Rfs*256 (on ENST00000344691 / NM_001001890.3; = p.A338Rfs*256 on NM_001754.5) | Frame Shift Del (DEL) | VAF 24/44 reads (55%) | called by mutect2, pindel, varscan2
- SPTBN5 | c.2057C>G p.A686G | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.085); called by muse, mutect2, varscan2
